Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABOT, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABOT-TTM1-A (Metastatic).

[page 1 of 14]
[REDACTED]

Surgical Specimens Report

Pg 1

Patient:
Unit#/Acct#:
Location:
Att Phys-Serv:
Ordering Phys:

Age:
Case#:
Acqn#:
Completed:
Received:
Collected:

Sex: [REDACTED]

+3
+0
+0

***** GROSS AND MICROSCOPIC EXAM *****
Specimen(s): LYMPH NODE-bxs

A. LYMPH NODE-bxs

Date of Surgery: [REDACTED] +0
Surgeon: [REDACTED]
Specimen: 4R AND 4L LYMPH NODES
Pre-op Diagnosis: MEDIASTINAL MASS, ENLARGED LYMPH NODES
Procedure: MEDIASTINOSCOPY
Clinical History: NONE

MEDIASTINAL NODES, 4R AND 4L (A AND B):
METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA, NAPSIN-A
AND TTF-1 POSITIVE, CONSISTENT WITH PULMONARY ORIGIN.

COMMENT: Tissue from both left and right sides (A and B) has metastatic adenocarcinoma. The tumor cells stain strongly positively for TTF-1, pancytokeratin, Napsin-A and CK-7. They have variable positivity for nuclear p63. The cells stain negatively for CK-5/6 and CK-20. These features are consistent with adenocarcinoma of pulmonary origin. Adequate tissue is present for EGFR and KRAS mutation analysis and ALK-1 FISH is clinically indicated and requested by the clinician. Flow cytometry negative for lymphoma. See separate report from [REDACTED]

Electronically Released By:
[REDACTED]

Received in the fresh state are two node fragments measuring 6 mm and 8 mm each. The cut surface is smooth and fleshy. A portion of the larger fragment is submitted for flow cytometry and the remainder is submitted for histologic sections in cassette A.
B. 4L lymph node biopsy: Received are multiple fragments of fleshy pinkish-tan nodal tissue ranging from 2-4 mm each. There are 17 or 18 separate small fragments are received. Some fragments are submitted for flow cytometry together with the tissue from specimen A. The remainder is submitted in cassette B for histologic evaluation. [REDACTED]
88307 x 2

ICD Codes: [REDACTED]

End of Report - [REDACTED] +3

[page 2 of 14]
Patient Name
Date of Birth
Gender
Medical Record #
Master Accession
Case No
Concurrent Cases

Client Name
Client ID#
Ordering Physician
Treating Physician
Date/Time Collected
Date/Time Received

+0
+21

FISH Study

4R Mediastinal Lymph Node Tissue ALK gene rearrangement by FISH:
Not Detected

Comment: ALK gene rearrangement was not detected using the Vysis ALK Break Apart FISH Probe Kit (Abbott Molecular). The absence of an ALK rearrangement suggests that the patient may not respond to treatment with XALKORI (crizotinib). Clinical correlation is suggested.

Reference range:

Not Detected: Less than 10% of cells with split signals (3' ALK and 5' ALK signals apart by greater than 2 times signal size or single 3' ALK signal) in 50 cells scored or less than 15% of cells with split signals in 100 cells scored.

Detected: Greater than 50% of cells with split signals (3' ALK and 5' ALK signals apart by greater than 2 times signal size or single 3' ALK signal) in 50 cells scored or, greater than or equal to 15% of cells with split signals in 100 cells scored.

Methodology:

After a pathologist determined the tumor area on an H&E slide from this formalin-fixed paraffin-embedded (FFPE) patient specimen, ALK gene rearrangement was assessed utilizing the Vysis ALK Break Apart FISH Kit (Abbott Molecular). The identification probes for LSI ALK 5' probe (SpectrumGreen) and LSI ALK 3' probe (SpectrumOrange) were applied, hybridized and assessed along with standard controls. At least 50 non-overlapping nuclei were analyzed and the localization of the LSI ALK 5' probe (green) and LSI ALK 3' probe (orange) signals were recorded and interpreted according to manufacturer's guidelines.

Intended Use:

The ALK FISH assay (Anaplastic Lymphoma Kinase) utilizes the Vysis ALK Break Apart Kit (Abbott Molecular) and is designed to detect rearrangements of the ALK gene in formalin-fixed paraffin embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens to aid in identifying those patients eligible for treatment with XALKORI (crizotinib). This test has been approved by the Food and Drug Administration (FDA).

[page 3 of 14]
Patient Name
Date of Birth
Gender
Medical Record #
Master Accession
Case No
Concurrent Cases

Client Name
Client ID#
Ordering Physician
Treating Physician
Date/Time Collected
Date/Time Received

+0
+21

KRAS Mutation Analysis

4R Mediastinal Lymph Node Tissue : KRAS Mutation Not Detected

Genotype Result:
Wild-type (No mutation identified)

Reference Range

Mutation Detected:
Unlikely to respond to anti-EGFR therapy.

Mutation Not Detected:
May respond to anti-EGFR therapy.

Comment: No KRAS mutations were detected by PCR. Activating mutations in BRAF (V600E), a downstream effector in the KRAS pathway, have also been described to identify patients who are unlikely to respond to anti-EGFR therapy (Di Nicolantonio et al., J Clin Oncol, Dec 10 2008). Additional BRAF mutational analysis can be performed, if clinically indicated (please call [redacted] to order this test).

Methodology: The tumor area on an H&E slide for this formalin-fixed paraffin-embedded (FFPE) patient specimen was identified by a pathologist. This region was selectively microdissected from the corresponding unstained slide(s), lysed and the DNA extracted. Real-time PCR using eight primer sets was used to amplify the region of the KRAS gene containing codons 12 and 13. A set of eight probes was used to specifically detect the wild-type and mutant sequences.

Intended Use: The KRAS mutation analysis by real-time PCR detects the wild-type sequence and seven known mutations associated with codons 12 and 13 of the KRAS oncogene. This assay is capable of detecting a mutation to 1% in a background of wild-type alleles. The intended use of this assay is to aid the treating physician in the selection of the appropriate therapy for the patient. Tumors harboring a KRAS mutation show relative insensitivity to anti-tyrosine kinase receptor therapies that signal through the RAS/RAF pathway. The results of this study are to be interpreted in context with other clinical findings in patient care management.

[page 4 of 14]
Patient Name
Date of Birth
Gender
Medical Record #
Master Accession
Case No
Concurrent Cases

Client Name
Client ID#
Ordering Physician
Treating Physician
Date/Time Collected
Date/Time Received

+0
+21

EGFR Mutation Analysis

4R Mediastinal Lymph Node Tissue: NO EGFR ALTERATION DETECTED

Genotype Result:

Wild-type (No EGFR alteration detected)

Reference Range

Alteration Detected: See Table

Alteration Not Detected*

Exon 19 deletion	Increased responsiveness to TKIs	Deletions in exon 19 confer ligand independent activation and increase the duration and activation of receptor signaling after ligand binding. These deletions result in the modified receptors being approximately 100-fold more sensitive than wild-type receptors to inhibition with TKIs. Reference (1)
G719S, G719A, G719C	Increased responsiveness to TKIs	Mutations at codon 719 in exon 18 are associated with response of NSCLC to gefitinib or erlotinib monotherapy (slightly more than 50%), although they are not as responsive as those with deletions in exon 19 or point mutations of codon 858 in exon 21. Reference (1)
L858R	Increased responsiveness to TKIs	The missense mutation L858R in exon 21 confers ligand independent activation and increases the duration and activation of receptor signaling after ligand binding. This mutation results in the modified receptors being more sensitive than wild-type receptors to inhibition with TKIs. Reference (1)
L861Q	Increased responsiveness to TKIs	The missense mutation L861Q in exon 21 confers ligand independent activation and increases the duration and activation of receptor signaling after ligand binding. This mutation results in a modified receptor that has been reported to be more sensitive than wild-type receptor to inhibition with TKIs. Reference (1)
S768I	Lack of responsiveness to TKIs	Mutations at codon 768 in exon 20 are associated with less responsiveness of NSCLC to gefitinib or erlotinib monotherapy. Reference (2)
T790M	Lack of responsiveness to TKIs	T790M point mutation in exon 20 is a frequent cause of secondary resistance to TKIs. It appears that TKI administration may select for a pre-existing T790M resistance clone. Reference (3)
Exon 20 Insertion	Lack of responsiveness to TKIs	Insertions in exon 20 have been associated with lack of clinical response of NSCLC to gefitinib or erlotinib monotherapy both in vitro and in patients despite the fact that they seem to activate EGFR to a similar degree as deletions in exon 19 or exon 21 mutations. This is a rare mutation however, and robust clinical data is lacking. Reference (2)
References:	(1) Lynch, Thomas J. et al. N Engl J Med 350(21): 2129, 2004. (2) Wu, Jenn-Yu et al. Clin Cancer Res 14(15):4877, 2008. (3) Kobayashi, Susumu et al. N Engl J Med 352(8):786, 2005.	

Methodology: The tumor area on an H&E slide for this formalin-fixed paraffin-embedded (FFPE) patient specimen was identified by a pathologist. This region was selectively microdissected from the corresponding unstained slide(s), lysed and the DNA extracted. The collected cells were lysed, and the genomic DNA was purified from the sample. Real-time PCR was used to evaluate specific mutations, deletions and insertions in the tyrosine kinase domain of the Epidermal Growth Factor Receptor (EGFR) gene. Eight reactions containing 30 primer and probe sets were used to target specific regions of exons 18-21 as well as the wild-type sequence.

Intended Use: The EGFR mutation analysis by real-time PCR is able to detect the wild-type sequence and 29 known mutations, deletions and insertions found in exons 18-21 of the EGFR tyrosine kinase domain. The results of this study are to be interpreted in context with other clinical findings in patient care management. The intended use of this assay is to aid the treating physician in the selection of the appropriate therapy for the patient. There is a significant association between EGFR mutation, especially exon 19 deletion, and response to TKI's. This assay is capable of detecting a mutation of 1-5% in a background of wild-type alleles. These mutations are linked to clinical responsiveness to EGFR inhibitors, such as gefitinib (Iressa) and erlotinib (Tarceva).

* An "Alteration Not Detected" result does not preclude the presence of an EGFR mutation since results depend on percent mutant sequences, adequate specimen integrity, absence of inhibitors, and sufficient DNA to be detected.

[page 5 of 14]
PET IMAGING W/CT SKULL-MID THGH

Patient:

MR#:

Ordered:

Facility:

Date: +11

Cat Scan

None

OBSERVATION-

WHOLE BODY PET CT SCAN- +11

PI-PET tumor init tx strategy

INDICATION-

This is an with history of lung cancer who presents for PET CT scan imaging for restaging purposes prior to treatment.

RADIOPHARMACEUTICALS-

15.08 millicuries F18 FDG IV right antecubital vein. Blood glucose 97 mg/dl.

TECHNIQUE- Following at least a 4-hour fasting, the patient's blood glucose was calculated to be 97 mg/deciliters. One hour following the injection of 15.08 mCi F-18 FDG IV, right wrist, low-dose CT images were obtained from the orbital meatal line through the pelvis. Then, PET images were obtained through the same region. Attenuation corrected images were constructed using the CT scan. Fused images of PET and CT were reviewed. 100 cc Omnipaque 350 intravenous contrast material and dilute oral contrast material was administered. The standard uptake values (SUV) is reported below are maximum values within a region of interest, expressed in grams per milliliters.

FINDINGS-

NECK-

There are bilateral hypermetabolic cervical lymph nodes, as follows.

[page 6 of 14]
Right level 2, 10 mm, 5.40 SUV.

Left level 2, 10 mm, 3.11 SUV.

Right level 3, 20 mm, 10.40 SUV.

Left level 3, 12 mm, 6.45 SUV.

There is a hypermetabolic focus in the right prevertebral soft tissue structures anterior to the CT vertebrae which measures approximately 16 mm and demonstrates metabolic activity of 5.77 SUV. This focus demonstrates a nodular contour and likely reflects additional adenopathy.

Bilateral salivary glands, aerodigestive tract, orbits, visualized brain parenchyma, paranasal sinuses and mastoid air cells are within normal limits.

CHEST-

There are multiple hypermetabolic mediastinal and hilar lymph nodes as follows.

Left paratracheal, 21 mm, 11.37 SUV.

Right paratracheal, 12 mm, 6.79 SUV.

Left hilar, 15 mm, 10.89 SUV.

Right hilar, 10 mm, 6.68 SUV.

Right subcarinal, 11 mm, 7.03 SUV.

Left descending periaortic, 7.5 mm, 3.46 SUV.

There are bilateral prominent axillary lymph nodes demonstrating a fatty hilum. These lymph nodes demonstrate a maximum metabolic activity of 1.94 SUV, consistent with reactive adenopathy.

There is a left sided MediPort with distal tip in the SVC. There is no abdominal aortic aneurysmal dilatation or dissection. There are postop changes of median sternotomy. there is no endotracheal or endobronchial mass lesion. There is mild cardiomegaly. There is physiological myocardial activity present. There is no pericardial effusion. Lung windows demonstrates symmetric aeration of lungs. There

[page 7 of 14]
is no pleural effusion or pneumothorax or focal airspace consolidation. There is a hypermetabolic spiculated right apical mass which measures 12 mm and demonstrates metabolic activity of 6.57 SUV. This nodule is located adjacent to the mediastinum (image 14).

There is a left sided cardiac pacemaker in place.

ABDOMEN/PELVIS-

There is no abnormal hypermetabolic activity seen within the abdomen or pelvis. There are calcified gallstones without evidence of cholecystitis. There is no pathologic hypermetabolic adenopathy. There is a nonmetabolically active 4.5 cm right renal cyst. There are two 10 mm cysts within the left hepatic lobe. There is a calcified granuloma in the left hepatic lobe as well. Liver is otherwise normal in appearance. Spleen, bilateral adrenal glands, left kidney and pancreas are normal in appearance. There is no abdominal aortic aneurysmal dilatation or dissection. there is no bowel obstruction. Appendix is normal in appearance. Urinary bladder is within normal limits.

MUSCULOSKELETAL-

There is a 21 mm focus of hypermetabolic within the right upper arm which demonstrates metabolic activity of 32.41 SUV. There is no underlying mass lesion appreciated. This may represent a vascular structure.

There is a 15 mm focus of hypermetabolic activity within the left aspect fo the sternum which appears to represent a subpleural based soft tissue nodule which demonstrates metabolic activity of 6.37 SUV. There appears to be underlying osseous erosion present as well.

There are multiple nonmetabolically reactive subcentimeter sclerotic foci seen throughout the skeletal system which may represent bone island verses osteoblastic mets.

IMPRESSION-

1. SPICULATED HYPERMETABOLIC RIGHT APICAL NODULE WHICH IS MOST CONSISTENT WITH NEOPLASTIC PROCESS, CONSISTENT WITH KNOWN HISTORY OF BRONCHOGENIC CARCINOMA.
2. HYPERMETABOLIC BILATERAL CERVICAL, MEDIASTINAL AND HILAR

[page 8 of 14]
ADENOPATHY
CONSISTENT WITH METASTATIC DISEASE.

3. HYPERMETABOLIC PLEURAL NODULE ADJACENT TO THE LEFT
STERNUM
CONSISTENT WITH METASTATIC DISEASE.

4. NONMETABOLICALLY ACTIVE HEPATIC CYSTS.

5. NONMETABOLICALLY ACTIVE RIGHT RENAL CYST.

6. OLD GRANULOMATOUS DISEASE.

7. INDETERMINATE HYPERMETABOLIC FOCUS WITHIN THE RIGHT UPPER
ARM
LIKELY REFLECTING ARTIFACT RELATED TO INJECTION SITE. NO
DEFINITE
UNDERLYING MASS LESION IS APPRECIATED. MRI WITH AND WITHOUT
CONTRAST
MAY PROVIDE ADDITIONAL DIAGNOSTIC INFORMATION IF CLINICALLY
INDICATED.

8. INDETERMINATE SUBCENTIMETER SCLEROTIC FOCI SEEN
THROUGHOUT THE
SKELETAL SYSTEM LIKELY REFLECTING BONE ISLANDS. OSTEOLASTIC
METS
CANNOT BE RULED OUT. RECOMMEND NUCLEAR MEDICINE WHOLE
BODY BONE SCAN
FOR FURTHER EVALUATION.

9. CHOLELITHIASIS WITHOUT CT EVIDENCE FOR ACUTE CHOLECYSTITIS.

CORRECTION- There is not a left-sided MediPort in place. There is a
left-sided cardiac pacemaker in place.

Electronically signed

[page 9 of 14]
Addendum Read By- [REDACTED]
Addendum Released Date Time- [REDACTED] +14

[page 10 of 14]
PET IMAGING W/CT SKULL-MID THGH

Patient:

MR#:

Ordered

Facility:

Date: +77

Cat Scan

None

OBSERVATION-

PET CT F-18 FDG SKULL-MIDTHIGH WITH CONTRAST- +77

PS- Subsequent treatment strategy.

INDICATION-

History of lung cancer. Today's exam is performed for treatment assessment. Patient has been undergoing chemotherapy.

COMPARISON-

PET CT with contrast +11

TECHNIQUE-

The patient has fasting blood glucose of 96 mg/deciliter. One-hour post injection of 16.72 millicuries of F-18 FDG, axial CT images were obtained from the skull base through the pelvis without contrast. Next, PET images were obtained from the skull base through the pelvis. CT attenuation correction was performed and fused images of PET and CT were obtained.

NECK FINDINGS-

Limited visualization of the lower portion of the brain is unremarkable. There is stable mild increased density within the posterior right ethmoid air cells and anterior right sphenoid sinus. The remainder of the paranasal sinuses and the mastoid air cells are grossly clear. There is a hypermetabolic lymph node along the base of the right neck along the carotid chain in the level 3/4 region, which has decreased activity and slight decrease in size. The SUV max is 7.2

[page 11 of 14]
compared to 10.4 previously. It measures 1.5 x 1.9 cm compared to 1.9 x 2.0 cm previously. A second smaller lymph node on the left side at the same level has slightly less activity and is not significantly changed in size. It has an SUV max of 4.1 with previous SUV max of 6.5. There is normal appearing enhancement of the great vessels.

CHEST FINDINGS-

There has been interval improvement of the mediastinal and bilateral hilar adenopathy. This is mainly related to decreased activity. A dominant hypermetabolic node in the superior left peritracheal region has an SUV max of 6.1 today compared to 11.4 previously. It does not appear significantly changed in size. It measures 1.9 x 1.9 cm, compared to 2.2 x 1.9 cm previously. Two additional nodes in the right paratracheal region have decreased in size and activity. They have an SUV max of 4.8 compared to 7.0 previously. The largest node in this area previously measured 1.5 cm compared to 1 cm today. There is persistent bilateral hilar adenopathy with increased activity. The activity has mildly decreased on the left and not significantly changed.

The area of involvement has not significantly changed. The SUV max on the right is 8.9 and the SUV max on the left is 9.4. This compares to 8.5 on the right previously and 10.9 on the left previously. A subcarinal hypermetabolic node has slightly decreased in size and mildly to moderately decreased in activity. It has an SUV max of 4.4 today compared to 7.1 previously. There is right infrahilar adenopathy, which is subcentimeter in size and has mildly decreased in activity. SUV max today is 5.4 compared to 5.9 previously. No pleural or pericardial effusions are seen. Cardiac pacemaker and right subclavian Medi-Port catheter are in place.

There is a persistent nodular hypermetabolic focus in the medial aspect of the right upper lobe bordering the mediastinum, which has an SUV max of 7.2 today compared to 6.8 previously. It has not significantly changed in size. An additional smaller focus of hypermetabolic activity is again seen in the left upper lobe, which does not appear significantly changed. It is subcentimeter in size and has an SUV max of 3.4. A pleural-based focus of hypermetabolic activity versus intermammary lymph node is again seen on the left and has not significantly changed. The SUV max is 3.4 today compared to 6.4 previously. There is some new mild hypermetabolic activity in the right axilla, which appears to correspond to several benign-appearing lymph nodes. This may be reactive in nature. Metastatic disease is not entirely excluded though thought to be less likely. The SUV max is 3.9.

There is asymmetric increased density in the left breast with an appearance suggestive of gynecomastia. No mass-like features are seen.

There is mild associated activity and this is similar on the previous

[page 12 of 14]
exam. It has not changed.

ABDOMEN FINDINGS-

There are stable hypometabolic fluid-attenuation areas within the left lobe of the liver most suggestive of cysts. Additional scattered small areas are present in the right lobe, which are stable. There is some layering hyperdensity within the gallbladder suggesting cholelithiasis as seen previously. A hypometabolic cyst is again seen arising from the medial lower pole of the right kidney. There is normal-appearing bilateral renal activity. The adrenal glands, pancreas, spleen, and loops of bowel have a normal appearance. Mild linear physiologic appearing bowel activity is seen. There is atherosclerosis of the abdominal aorta without aneurysm. No hypermetabolic or enlarged lymph nodes are seen. No free fluid is seen.

PELVIS FINDINGS-

There is normal-appearing bladder and bowel activity. Prostate gland is mildly enlarged. The bladder wall appears thickened, however, the lumen is mostly decompressed and this is probably artifactual. No intrapelvic or inguinal hypermetabolic lymph nodes are seen. No free fluid is seen.

MUSCULOSKELETAL FINDINGS-

There is heterogeneous marrow activity throughout the lumbar spine, which is stable and of uncertain significance. There is a chronic compression fracture of L2. There are some tiny sclerotic foci within the lumbar vertebrae, which are stable. There is relative decreased activity of the thoracic spine compared to the lumbar spine.

IMPRESSION-

IMPRESSION-

1. INTERVAL DECREASE IN ACTIVITY INVOLVING THE MEDIASTINAL, LEFT HILAR, AND LOWER CERVICAL LYMPH NODES COMPATIBLE WITH A RESPONSE TO THERAPY. THERE IS SIGNIFICANT RESIDUAL DISEASE PRESENT.
2. STABLE BILATERAL UPPER LOBE PULMONARY NODULES WITH ASSOCIATED

[page 13 of 14]
ACTIVITY.

3. TWO NEW FOCI OF ACTIVITY IN THE RIGHT AXILLA, WHICH CORRESPOND TO BENIGN-APPEARING LYMPH NODES. THIS MAY BE REACTIVE ACTIVITY. EARLY METASTATIC DISEASE CANNOT BE EXCLUDED.

4. STABLE APPEARANCE OF THE HETEROGENEOUS LUMBAR MARROW ACTIVITY AND THIS IS OF UNCERTAIN SIGNIFICANCE. CONTINUED FOLLOW UP IS RECOMMENDED.

[page 14 of 14]
Patient:

MR#:

Ordered

Facility:

Date:

+588

OBSERVATION:

Exam: CT chest/abdomen/pelvis with contrast

Indication: Lung cancer-followup

Technique: Images from the lung apex to the symphysis pubis with 100 mL's Omnipaque 350 IV

Comparison study: ~+331

Findings:

Chest

The lungs show no masses, nodules, infiltrates, or effusions.

There is no suspicious hilar or mediastinal adenopathy.

Pacemaker and CABG markers are noted.

The aorta and heart are normal in size.

Abdomen/pelvis

Simple cysts of the liver and right kidney are again seen, stable.

A few stones are noted within a contracted gallbladder.

There is no biliary dilatation.

The abdominal organs are otherwise normal in appearance.

Both kidneys excrete contrast with no hydronephrosis.

There is no bowel dilatation.

No abnormal mass, fluid collection, adenopathy, or inflammatory process is seen.

Two lucent foci within the L4 vertebral body are stable in appearance.

There are no suspicious bone lesions.

IMPRESSION:

No evidence of recurrent or metastatic disease.

IMPRESSION:

Electronically signed

+588

Source: NCI Genomic Data Commons file bea28a93-e655-4d5e-bea8-ea07b194605d (ER0137 ER-ABOT Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).